Somatic mutation profile of tumor specimen TCGA-HW-8319-01A (aliquot TCGA-HW-8319-01A-11D-2395-08) from TCGA case TCGA-HW-8319, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 34.4 years (12,557 days).
Specimen TCGA-HW-8319-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8763dd9b-855d-410c-9dc0-67efeb77f2a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HW-8319-10A (Blood Derived Normal), aliquot TCGA-HW-8319-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b78b369-1c53-4dd4-b611-cd40eb3b304c

The open-access MAF lists 34 somatic variants for this specimen: 26 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 23, Silent 8, Frame Shift Del 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 29/79 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 25/66 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 26/48 reads (54%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AKAP5 | c.1264_1268del p.I422Qfs*? (on ENST00000320636; = p.I422Qfs*18 on NM_004857.3) | Frame Shift Del (DEL) | VAF 26/106 reads (25%) | catalogued as rs781537777; called by pindel, varscan2
- ANKRD28 | c.2557G>A p.D853N | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.942); catalogued as COSV67519555; called by muse, varscan2
- ATRX | c.662G>A p.R221K | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV64876391, COSV64879357; called by muse, mutect2, varscan2
- DGCR2 | c.1398C>T p.D466= | Splice Region (SNP) | VAF 14/48 reads (29%) | catalogued as rs146027196; called by muse, mutect2
- ERAP2 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV65940845; called by muse, mutect2
- HIVEP3 | c.6064G>A p.G2022S | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as COSV56020575; called by muse, mutect2, varscan2
- ISLR | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs770282258, COSV51434164; called by muse, mutect2, varscan2
- LIMK1 | c.263C>G p.S88C | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV60283563; called by muse, mutect2, varscan2
- LRRCC1 | c.248T>G p.L83R | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64484825; called by muse, mutect2, varscan2
- MPPE1 | c.187C>G p.Q63E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV100012995; called by muse, mutect2, varscan2
- MRGPRX3 | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 27/38 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as rs551318965, COSV66934227; called by muse, mutect2, varscan2
- MYH15 | c.1283C>T p.T428I | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as COSV56316181; called by muse, mutect2, varscan2
- MYH7B | c.2528G>A p.R843H | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs370697289; called by muse, mutect2, varscan2
- OR52I2 | c.747C>G p.I249M | Missense Mutation (SNP) | VAF 69/114 reads (61%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.49); catalogued as COSV57045838; called by muse, mutect2, varscan2
- PBDC1 | c.342C>G p.D114E | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV64896081; called by muse, mutect2, varscan2
- PCDHGB5 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs538358679, COSV53913457; called by muse, mutect2, varscan2
- PLS3 | c.1676T>G p.I559S | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV56781062; called by muse, mutect2, varscan2
- PTGR2 | c.877A>G p.K293E | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV50866596; called by muse, mutect2, varscan2
- RASEF | c.2036C>G p.A679G | Missense Mutation (SNP) | VAF 81/258 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV64588142; called by muse, mutect2, varscan2
- SATB1 | c.1189G>T p.A397S | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58671685; called by muse, mutect2, varscan2
- SCN2A | c.3242G>C p.S1081T | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV51850809; called by muse, mutect2, varscan2
- SLC4A7 | c.2413C>G p.L805V | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.142); catalogued as COSV55400914; called by muse, mutect2, varscan2
- ZNF189 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.258); catalogued as rs766896414, COSV52276413; called by muse, mutect2, varscan2
- CRAMP1 | c.1314C>T p.D438= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs776839175, COSV51963095; called by muse, mutect2, varscan2
- HCN1 | c.2289G>A p.P763= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as rs759408275, COSV57502023; called by muse, mutect2, varscan2
- MPP7 | c.1431A>G p.L477= | Silent (SNP) | VAF 52/101 reads (51%) | catalogued as rs200989770, COSV61736025; called by muse, mutect2, varscan2
- OR2T1 | c.582C>T p.Y194= | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as rs148427102; called by muse, mutect2, varscan2
- OR51L1 | c.807T>C p.H269= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV58625359; called by muse, mutect2, varscan2
- OR9G4 | c.414C>T p.T138= | Silent (SNP) | VAF 16/208 reads (8%) | catalogued as rs149257582; called by muse, mutect2
- ZC3H4 | c.2685C>T p.A895= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV53415616; called by muse, mutect2, varscan2
- ZNF275 | c.426G>A p.A142= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as rs1315753478, COSV64705147; called by muse, mutect2, varscan2
